Somatic mutation profile of cancer-model specimen HCM-CSHL-0434-C24-85M (3D Organoid; aliquot HCM-CSHL-0434-C24-85M-01D-A78U-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0434-C24, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Extrahepatic bile duct; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 61.0 years (22,282 days).
Specimen HCM-CSHL-0434-C24-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e794e40-8549-43ca-b93e-764cb1447043.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0434-C24-10A (Blood Derived Normal), aliquot HCM-CSHL-0434-C24-10A-01D-A78U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4cccbbe6-abf2-4e2b-a2db-f0579d80ce00

The open-access MAF lists 104 somatic variants for this specimen: 65 protein-altering or splice-affecting, 25 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 25, Intron 7, Nonsense Mutation 4, Splice Site 2, RNA 2, 5'UTR 2, In Frame Del 1, 5'Flank 1, Frame Shift Del 1, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 281/289 reads (97%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 389/389 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ASCC3 | c.4729G>A p.A1577T | Missense Mutation (SNP) | VAF 107/330 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.312); catalogued as rs187359221; called by muse, mutect2, varscan2
- CAPRIN1 | c.1591G>A p.E531K | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as rs1324425337; called by muse, mutect2, varscan2
- CD44 | c.1077G>C p.W359C | Missense Mutation (SNP) | VAF 44/438 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.533); catalogued as COSV99555945; called by muse, mutect2
- CFAP46 | c.7202G>A p.R2401Q | Missense Mutation (SNP) | VAF 65/116 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs375364632, COSV99583945; called by muse, mutect2, varscan2
- CFL1 | c.106G>A p.V36M | Missense Mutation (SNP) | VAF 174/410 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as COSV57380536; called by muse, mutect2, varscan2
- CHST15 | c.892G>A p.V298I | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs757439959, COSV60562927; called by muse, mutect2
- CHST6 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as CM053804, CM065072, COSV60001469; called by muse, mutect2
- DENND4A | c.4498C>T p.R1500* | Nonsense Mutation (SNP) | VAF 19/72 reads (26%) | catalogued as rs761994040, COSV71265716; called by muse, mutect2, varscan2
- DNAH7 | c.8779C>T p.Q2927* | Nonsense Mutation (SNP) | VAF 35/99 reads (35%) | catalogued as rs374570869; called by muse, mutect2, varscan2
- DRD2 | c.967G>A p.A323T | Missense Mutation (SNP) | VAF 38/594 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.108); catalogued as rs527942874; called by muse, mutect2
- DUSP7 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 321/322 reads (100%) | SIFT tolerated (0.26); PolyPhen benign (0.227); catalogued as rs879043778; called by muse, mutect2, varscan2
- ESX1 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 119/120 reads (99%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs782576955; called by muse, mutect2, varscan2
- FARP2 | c.288+2T>C p.X96_splice | Splice Site (SNP) | VAF 86/161 reads (53%) | catalogued as rs1166151853; called by muse, mutect2, varscan2
- FLG | c.4387G>A p.G1463R | Missense Mutation (SNP) | VAF 178/653 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1341902735; called by muse, mutect2, varscan2
- GLP2R | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 82/82 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs575133662, COSV52324255; called by muse, mutect2, varscan2
- GMCL2 | c.19C>T p.R7W | Missense Mutation (SNP) | VAF 42/63 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as rs1368534206; called by muse, mutect2
- GRIA1 | c.2093G>A p.R698Q | Missense Mutation (SNP) | VAF 55/268 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as rs531706550, COSV53596718; called by muse, mutect2, varscan2
- GRK3 | c.1181A>G p.H394R | Missense Mutation (SNP) | VAF 12/230 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.215); catalogued as rs1490381903; called by muse, mutect2
- HSPB8 | c.136T>C p.S46P | Missense Mutation (SNP) | VAF 11/260 reads (4%) | catalogued as rs1395114117; called by muse, mutect2
- KLHL42 | c.1345G>A p.D449N | Missense Mutation (SNP) | VAF 472/513 reads (92%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.996); catalogued as rs374664683; called by muse, mutect2, varscan2
- KRT28 | c.583G>A p.G195R | Missense Mutation (SNP) | VAF 31/264 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs771268029, COSV60683747; called by muse, mutect2, varscan2
- LRRTM4 | c.32G>A p.G11D | Missense Mutation (SNP) | VAF 59/141 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1479336871, COSV69140756; called by muse, mutect2, varscan2
- LTBP1 | c.2878G>T p.E960* (on ENST00000404816 / NM_206943.4; = p.E634* on NM_000627.4) | Nonsense Mutation (SNP) | VAF 165/166 reads (99%) | catalogued as COSV100617209, COSV63195429; called by muse, mutect2, varscan2
- MAGEB4 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 136/136 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as rs770408937, COSV66775187; called by muse, mutect2, varscan2
- MPDZ | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 129/129 reads (100%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs779501527; called by muse, mutect2, varscan2
- MYO3A | c.1444G>A p.D482N | Missense Mutation (SNP) | VAF 73/266 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.734); catalogued as COSV56320262; called by muse, mutect2, varscan2
- NMUR2 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 85/294 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as rs764432864, COSV54918182; called by muse, mutect2, varscan2
- PLXNA2 | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 53/100 reads (53%) | SIFT tolerated (0.22); PolyPhen benign (0.127); catalogued as rs778037020; called by muse, mutect2, varscan2
- PPIA | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 89/421 reads (21%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.005); catalogued as rs767375293, COSV63534169; called by muse, mutect2, varscan2
- SIPA1L2 | c.161C>T p.S54L | Missense Mutation (SNP) | VAF 82/179 reads (46%) | SIFT tolerated (0.52); PolyPhen benign (0.018); catalogued as rs368264412; called by muse, mutect2, varscan2
- SKOR1 | c.2137G>A p.D713N | Missense Mutation (SNP) | VAF 105/225 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as COSV58244084; called by muse, mutect2, varscan2
- SLC24A3 | c.788A>C p.Q263P | Missense Mutation (SNP) | VAF 279/613 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.112); catalogued as COSV100043446; called by muse, mutect2, varscan2
- SORCS3 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs896551212; called by muse, mutect2, varscan2
- TIMM8B | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.193); catalogued as rs771329668; called by muse, mutect2, varscan2
- TMPRSS6 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 255/622 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.089); catalogued as rs1270960721, COSV60976662; called by muse, mutect2, varscan2
- TUB | c.124C>T p.R42C (on ENST00000299506 / NM_177972.3; = p.R97C on NM_003320.4) | Missense Mutation (SNP) | VAF 79/210 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs772509519; called by muse, mutect2, varscan2
- TUBA3C | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 81/139 reads (58%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs372020555, COSV67139306; called by muse, mutect2, varscan2
- VPS13D | c.8530G>T p.D2844Y | Missense Mutation (SNP) | VAF 156/156 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); catalogued as rs1425394183; called by muse, mutect2, varscan2
- XPO6 | c.2612G>A p.R871K | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.056); catalogued as rs780775153; called by muse, mutect2, varscan2
- ZBED9 | c.1220G>A p.R407Q | Missense Mutation (SNP) | VAF 65/104 reads (63%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.953); catalogued as rs185476387, COSV71729796; called by muse, mutect2, varscan2
- AP1G2 | c.1582del p.L528Sfs*5 | Frame Shift Del (DEL) | VAF 78/464 reads (17%) | called by mutect2, pindel, varscan2
- ARID3C | c.213G>T p.E71D | Missense Mutation (SNP) | VAF 188/188 reads (100%) | SIFT tolerated (0.17); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- CACNG8 | c.637T>G p.F213V | Missense Mutation (SNP) | VAF 64/1172 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- DACT1 | c.89G>C p.R30P | Missense Mutation (SNP) | VAF 253/339 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EP300 | c.2046G>A p.M682I | Missense Mutation (SNP) | VAF 44/492 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0.035); called by muse, mutect2
- GON4L | c.5788G>A p.A1930T | Missense Mutation (SNP) | VAF 207/391 reads (53%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGSF1 | c.2938G>C p.V980L | Missense Mutation (SNP) | VAF 101/102 reads (99%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- NPAS2 | c.58_60del p.K20del | In Frame Del (DEL) | VAF 14/94 reads (15%) | called by pindel, varscan2
- PPHLN1 | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, varscan2
- PPHLN1 | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.095); called by muse, varscan2
- PRKDC | c.11396G>C p.R3799T | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- PRPF6 | c.2029-1G>A p.X677_splice | Splice Site (SNP) | VAF 217/464 reads (47%) | called by muse, mutect2, varscan2
- PZP | c.1669G>C p.E557Q | Missense Mutation (SNP) | VAF 57/121 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- RHO | c.13G>T p.E5* | Nonsense Mutation (SNP) | VAF 12/242 reads (5%) | called by muse, mutect2
- SEMA5A | c.1468T>C p.Y490H | Missense Mutation (SNP) | VAF 13/323 reads (4%) | SIFT tolerated (0.61); PolyPhen benign (0.013); called by muse, mutect2
- TMEM8B | c.1102C>A p.R368S | Missense Mutation (SNP) | VAF 60/60 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- TTLL4 | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 44/180 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBR5 | c.5366G>A p.S1789N | Missense Mutation (SNP) | VAF 197/427 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- USP33 | c.1904T>A p.F635Y | Missense Mutation (SNP) | VAF 11/216 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- WFDC1 | c.478T>C p.Y160H | Missense Mutation (SNP) | VAF 201/323 reads (62%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- ZNF26 | c.1118G>A p.G373D | Missense Mutation (SNP) | VAF 242/242 reads (100%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF649 | c.878G>A p.S293N | Missense Mutation (SNP) | VAF 22/344 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2
- ZSWIM5 | c.796C>T p.L266F | Missense Mutation (SNP) | VAF 71/309 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- AJAP1 | c.717C>T p.S239= | Silent (SNP) | VAF 32/32 reads (100%) | catalogued as rs377710853; called by muse, varscan2
- ARMC4 | c.1668C>T p.A556= | Silent (SNP) | VAF 227/427 reads (53%) | catalogued as rs761407359; called by muse, mutect2, varscan2
- C3orf84 | c.150G>A p.A50= | Silent (SNP) | VAF 12/128 reads (9%) | catalogued as rs375093494; called by muse, mutect2
- CD36 | c.240C>T p.S80= | Silent (SNP) | VAF 74/293 reads (25%) | catalogued as rs776269710; called by muse, mutect2, varscan2
- CLUH | c.3828C>T p.A1276= (on ENST00000435359; = p.A1315= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/37 reads (54%) | catalogued as rs778665976, COSV70928918; called by muse, mutect2, varscan2
- DLGAP2 | c.933G>A p.T311= | Silent (SNP) | VAF 173/402 reads (43%) | catalogued as rs746806848; called by muse, mutect2, varscan2
- FAM53C | c.222G>C p.L74= | Silent (SNP) | VAF 54/135 reads (40%) | called by muse, mutect2, varscan2
- FBXO28 | c.858C>T p.R286= | Silent (SNP) | VAF 141/325 reads (43%) | called by muse, mutect2, varscan2
- FCGBP | c.9576G>A p.A3192= | Silent (SNP) | VAF 146/4374 reads (3%) | catalogued as rs764579451; called by muse, mutect2
- FOXG1 | c.1179G>A p.S393= | Silent (SNP) | VAF 50/895 reads (6%) | catalogued as COSV57395555; called by muse, mutect2
- HAMP | c.210C>T p.C70= | Silent (SNP) | VAF 182/2334 reads (8%) | catalogued as rs760104316, COSV55885844; called by muse, mutect2
- HECA | c.1620C>T p.L540= | Silent (SNP) | VAF 5/82 reads (6%) | catalogued as rs1380380608, COSV62768603; called by muse, mutect2
- HOXB3 | c.127C>T p.L43= | Silent (SNP) | VAF 288/454 reads (63%) | called by muse, mutect2, varscan2
- HSPG2 | c.7662C>T p.N2554= | Silent (SNP) | VAF 343/343 reads (100%) | called by muse, mutect2, varscan2
- NRG1 | c.1593C>T p.Y531= (on ENST00000405005 / NM_013964.5; = p.Y536= on NM_013956.5) | Silent (SNP) | VAF 174/369 reads (47%) | catalogued as rs576124928, COSV55153115; called by muse, mutect2, varscan2
- OCA2 | c.1221C>T p.F407= | Silent (SNP) | VAF 101/249 reads (41%) | catalogued as rs370349105; called by muse, mutect2, varscan2
- OR5C1 | c.732C>T p.T244= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs532966704, COSV101030530; called by muse, mutect2, varscan2
- ORAI2 | c.489C>T p.A163= | Silent (SNP) | VAF 230/515 reads (45%) | catalogued as rs769632596; called by muse, mutect2, varscan2
- SH3TC2 | c.2964G>A p.L988= | Silent (SNP) | VAF 20/411 reads (5%) | catalogued as rs1189055074, COSV60466406; called by muse, mutect2
- SHANK1 | c.6015C>T p.P2005= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as rs753950279, COSV53251529; called by muse, mutect2, varscan2
- SLC26A4 | c.474C>T p.D158= | Silent (SNP) | VAF 262/493 reads (53%) | catalogued as COSV55915305; called by muse, mutect2, varscan2
- SLC6A18 | c.1257C>T p.F419= | Silent (SNP) | VAF 53/301 reads (18%) | catalogued as rs757382342, COSV57250970; called by mutect2, varscan2
- SLC9A9 | c.1404C>T p.L468= | Silent (SNP) | VAF 147/286 reads (51%) | catalogued as rs576013614, COSV100339003, COSV57235318; called by muse, mutect2, varscan2
- TP73 | c.1863C>T p.A621= | Silent (SNP) | VAF 182/183 reads (99%) | called by muse, mutect2, varscan2
- ZNF862 | c.58T>C p.L20= | Silent (SNP) | VAF 108/108 reads (100%) | called by muse, mutect2, varscan2
- C16orf87 | c.-3A>G | 5'UTR (SNP) | VAF 50/190 reads (26%) | called by muse, mutect2, varscan2
- C19orf12 | chr19:29699652 T>C | 3'Flank (SNP) | VAF 207/815 reads (25%) | called by muse, mutect2, varscan2
- CFAP221 | c.2318+1423C>T | Intron (SNP) | VAF 10/30 reads (33%) | catalogued as rs548777396, COSV99733393; called by muse, mutect2
- CLOCK | c.1206+26T>A | Intron (SNP) | VAF 38/140 reads (27%) | catalogued as rs1431906788; called by mutect2, varscan2
- LINC01164 | n.673_675delinsCCA | RNA (TNP) | VAF 11/102 reads (11%) | called by muse*, mutect2*, pindel, varscan2*
- MCF2L2 | c.77-10749del | Intron (DEL) | VAF 65/177 reads (37%) | called by mutect2, pindel, varscan2
- MLLT6 | c.1943-59G>A | Intron (SNP) | VAF 37/292 reads (13%) | catalogued as rs927454997; called by muse, mutect2, varscan2
- MTHFD2L | chr4:74157926 T>C | 5'Flank (SNP) | VAF 144/220 reads (65%) | catalogued as rs1299716458; called by muse, mutect2, varscan2
- REPIN1 | c.-92C>G | 5'UTR (SNP) | VAF 170/170 reads (100%) | catalogued as rs1367020694; called by muse, mutect2, varscan2
- SCOC-AS1 | n.6637C>T | RNA (SNP) | VAF 54/193 reads (28%) | catalogued as rs940726834; called by muse, mutect2, varscan2
- SLC26A3 | c.1677+28dup | Intron (INS) | VAF 181/342 reads (53%) | catalogued as rs771040356; called by mutect2, pindel*, varscan2
- SLC39A9 | c.*3077C>T | 3'UTR (SNP) | VAF 46/46 reads (100%) | called by muse, mutect2, varscan2
- TGFBI | c.459+22C>T | Intron (SNP) | VAF 38/55 reads (69%) | catalogued as rs749930646; called by muse, mutect2, varscan2
- ZEB1 | c.58+43931G>A | Intron (SNP) | VAF 207/559 reads (37%) | catalogued as rs3895218; called by muse, mutect2, varscan2
